Gene-level copy-number profile of specimen HCM-BROD-0564-C71-85R from HCMI case HCM-BROD-0564-C71, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 65.5 years (23,928 days).
Specimen HCM-BROD-0564-C71-85R: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: 3D Neurosphere; Preservation method: Frozen; Passage count: 4.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 91a530b1-2b44-4743-a187-30ca3c11f3a3.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-BROD-0564-C71-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,221 have no estimate.
https://portal.gdc.cancer.gov/files/2e128a0c-8991-4911-a16b-e1b3a02a721b

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 4; copy number 2: 4,839; copy number 3: 14,877; copy number 4: 33,994; copy number 5: 1,870; copy number 6: 2,768; copy number 7: 6; copy number 8: 1; copy number 10: 1; copy number 56: 23; copy number 57: 19.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 43 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr7:153,449,429–153,449,875, 1 gene, copy number 10: PAXBP1P1.
- chr15:75,527,150–75,942,511, 23 genes, copy number 56 (within-gene range 4–56): AC105036.3, SNUPN, AC105020.3, AC105020.2, IMP3, AC105020.6, AC105020.5, SNX33, CSPG4, AC105020.4, AC105020.1, ODF3L1, DNM1P35, AC019294.2, PPIAP47, AC019294.3, MIR4313, AC019294.1, RN7SL319P, DNM1P49, UBE2Q2, RN7SL510P, FBXO22.
- chr17:1,716,523–2,063,241, 19 genes, copy number 57 (within-gene range 4–57): WDR81, AC130343.1, SERPINF2, SERPINF1, SMYD4, RPA1, AC130689.1, RTN4RL1, AC099684.2, AC099684.1, AC099684.3, DPH1, AC090617.10, OVCA2, AC090617.3, AC090617.5, MIR132, MIR212, HIC1.

Autosomal genes at a single copy (total copy number 1): 4. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
